Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84S, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84S-01A (Primary Tumor).

[page 1 of 3]
Requested
Collected
Received
Printed

DOB :
Sex : Male
Ph :

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

with history of seizures. Underwent resection of left frontal intra-axial lesion.

MACROSCOPIC:

'Brain tumour'. The specimen consists of multiple pieces of fragmented brain tissue measuring 35x35xup to 12mm. All embedded. (Blocks A to D)

MICROSCOPIC:

STRUCTURED REPORT FOR TUMOURS OF THE CENTRAL NERVOUS SYSTEM

Adapted from Tumours of the Central Nervous System Structured Reporting Protocol based on WHO classification 2007, 4th Edition. First Edition 2011.

CLINICAL SUMMARY:

Date of Birth/Age:
Sex:
Requesting Clinician:
Treating Clinician(s):
Clinical history on request form:

Ancillary tests requested:
Other clinical history-source:

ICD O-3

th history of seizures. Underwent resection of a left frontal intra-axial lesion.

CT angiogram report from states clinical history of dysphasia for two months, family history of frontal lobe tumour. There was an ill defined low density lesion in the left frontal lobe with an internal linear focus of calcification and mild mass effect, raising a concern for a low grade neoplasm. There was no aneurysm or AV malformation. An MRI brain on owed a heterogeneous left mesial frontal mass involving the superior frontal and cingulate gyri, at its deep margin extending down to and involving the left lateral fibres of the body of the corpus callosum. There was mass effect. There were foci of either dystrophic calcification or haemorrhage within the inferior portion of the tumour.

Seizures. CT report states dysphasia for two months.
Not known
None given
None known
Family history of frontal lobe tumour ?nature.
See above
Contrast enhancement absent.

Left frontal and corpus callosum

Presenting symptoms:
Duration of symptoms:
Previous tumour history:
Current and previous treatment:
Family history:
Imaging findings:

Anatomical site of lesion/s:
Intra-axial:
Extra-axial:

Clinical diagnosis or differential diagnosis:

Not given.

Oligodendroglioma, grade III
9451/3
Site Brain, supratentorial NOS
C71.0
path
Brain frontal lobe
C71.1
7/10/30/13

[page 2 of 3]
Ref by

MACROSCOPIC SPECIMEN SUMMARY:

Specimen type(s):	Multiple pieces of brain tissue
Number of specimens:	One
Dimensions:	35x35x12mm
Specimen received in:	Formalin
Triage of fresh tissue:	Not performed
Fixation:	Formalin
Amount of unprocessed tissue:	None

MICROSCOPIC FEATURES:

Microscopic description: The cortex and white matter are diffusely infiltrated by a glioma. In many areas, the tumour is of low cellularity, with regular, round nuclei and some cytoplasmic clearing. There are areas of calcification, and areas of microcystic degeneration. There is a prominent capillary vascular network. Some vessels show perivascular foamy macrophages. In the areas of low cellularity, there are very few mitoses, very few P53 positive cells and a proliferation index of less than 1%. In addition, there are highly cellular areas, where the nuclei are still predominantly round but show some pleomorphism and irregularity. There are areas with a myxoid background. In these cellular areas, there are up to five mitoses per high power field, the proliferation index is 50-75%, and there are 5-10% P53 positive cells. In block B, there is one very tiny focus of possible early microvascular proliferation, although this is not definite. IDH1 staining is positive throughout. There is little glial fibrillary acidic protein staining in the tumour cells themselves. Neuronal markers are negative.

Proliferation index (Ki67):	Up to 50-75%
p53:	Up to 5-10%
IDH1:	Positive
Mitoses:	Up to fifty per ten high power fields.
Distance between tumour and nearest dural/deep resection margins:	Tumour reaches margins of biopsies

IMMUNOHISTOCHEMICAL STAINS:

Positive:	Block: A and D
Negative:	IDH1, P53 (maximum 5-10%), GFAP (minimal staining)
Interpretation:	NeuN, synaptophysin
	Glial neoplasm

MOLECULAR PATHOLOGY AND OTHER TESTING IF REQUIRED:

FISH 1p 19q and EGFR amplification:	Block: A. Patient agreement: required. As there is no Medicare rebate for this test, an account will be sent to the patient. Therefore, arrangements for testing can only be made with the patient's informed consent. The estimated cost of this test is . If you have the patient's consent and wish to proceed, please fax a signed request form to and the necessary arrangements for testing will be made. A supplementary report will follow.
MGMT promoter methylation:	Probably not indicated in this case.
IDH1/IDH2 exon 4 sequencing:	Not indicated in this case, as immunohistochemistry positive.
Clinical trials (with ethics):	Block: A. Tumour 100%
Research block requests with ethics approval when no longer required for	

Surge
UK

Norm

Pos-Act
Fib

Pos-Act
Fib

Pos-Act
Fib

Pos-Act
Fib

Pos-Act
Fib

Pos-Act
Fib

Pos-Act
Fib

[page 3 of 3]
diagnosis:

Block: D.

Note: Any further results will be issued as a supplementary report.

LINEAGE:

Glial (favour oligodendroglial)

OVERALL COMMENT/SUMMARY:

The appearance is that of a diffuse glioma with morphological features of oligodendroglioma. There are large areas which appear WHO grade 2, but there are also foci which are regarded as WHO grade 3, on the basis of high cellularity, mitotic rate and some nuclear pleomorphism. The tiny focus of possible early microvascular proliferation would be acceptable for anaplastic (grade 3) oligodendroglioma, but would be of more concern in an astrocytic neoplasm. Confirmation of the diagnosis of oligodendroglioma by FISH testing for 1p19q deletion and EGFR amplification is highly recommended (patient permission required, see above).

DIAGNOSTIC SUMMARY:

Specimen type:
Tumour site and laterality:
WHO 2007 tumour type:
WHO 2007 grade:

Multiple tumour biopsies
Left frontal
Anaplastic oligodendroglioma (FISH confirmation recommended)
III with areas of grade II

ICD-O-3 CODE:

DIAGNOSIS:

LEFT FRONTAL TUMOUR

ANAPLASTIC OLIGODENDROGLIOMA GRADE III WITH AREAS OF GRADE II

Reported by

Tests Completed: Histo. FINAL REPORT

Clinical Notes:

Source: NCI Genomic Data Commons file 192e2f44-7b1e-4871-acc4-d190821f4678 (TCGA-TM-A84S.286FC4C6-07CD-4056-B6EE-C30619069A34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).